Somatic mutation profile of tumor specimen 0DI5FL from CCDI case PBBVDK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,303 days).
Specimen 0DI5FL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5adc61d-21d8-4a05-9822-bf7aee6ac464.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI5EF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cc72bb8-e03c-4519-a9d3-fffb510cb438

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1, Nonsense Mutation 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 473/1006 reads (47%) | catalogued as rs1561575998, CM053764, COSV57328302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP40 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 324/997 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as rs765883438; called by muse, mutect2, varscan2
- EN1 | c.382G>C p.V128L | Missense Mutation (SNP) | VAF 117/398 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- KIR2DL1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBED4 | c.2796C>G p.S932= | Silent (SNP) | VAF 248/926 reads (27%) | catalogued as rs374917157; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- GEMIN6 | c.*60G>A | 3'UTR (SNP) | VAF 79/242 reads (33%) | catalogued as rs1307138822, COSV56140376; called by muse, mutect2, varscan2
